Somatic mutation profile of tumor specimen TCGA-AA-3982-01A (aliquot TCGA-AA-3982-01A-02W-0995-10) from TCGA case TCGA-AA-3982, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.6 years (27,608 days).
Specimen TCGA-AA-3982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03847b85-2cd5-4dcd-bc93-da8f7962caa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3982-10A (Blood Derived Normal), aliquot TCGA-AA-3982-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d89673e9-37c4-47e5-b905-b61bc0b33591

The open-access MAF lists 129 somatic variants for this specimen: 103 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Nonsense Mutation 10, Splice Site 4, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 50/165 reads (30%) | catalogued as rs104893956, CM940378, COSV52803366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3011G>T p.G1004V | Missense Mutation (SNP) | VAF 70/685 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100229170; called by muse, mutect2, varscan2
- ADCY8 | c.2779T>A p.F927I | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99653141; called by muse, mutect2
- AFF2 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.521); catalogued as COSV100650555, COSV100651086; called by muse, mutect2, varscan2
- AFF2 | c.2603A>T p.K868M | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53975964, COSV53982508; called by muse, mutect2, varscan2
- AKAP13 | c.5570C>A p.S1857* (on ENST00000394518 / NM_007200.5; = p.S1861* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 47/133 reads (35%) | catalogued as COSV100774115; called by muse, mutect2, varscan2
- AMBN | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs867402927, COSV100534370, COSV100534409; called by muse, mutect2, varscan2
- AMOTL1 | c.161T>A p.L54* | Nonsense Mutation (SNP) | VAF 34/332 reads (10%) | catalogued as COSV100133863, COSV54416637; called by muse, mutect2, varscan2
- APC | c.1626+1G>C p.X542_splice | Splice Site (SNP) | VAF 42/222 reads (19%) | catalogued as COSV99968917; called by muse, mutect2, varscan2
- ARID1A | c.2332G>T p.G778* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100252419, COSV61377609; called by muse, mutect2, varscan2
- BACH1 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54517229; called by muse, mutect2, varscan2
- BMERB1 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757365966, COSV55509794; called by muse, mutect2, varscan2
- C11orf53 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1213979050, COSV54720905; called by muse, mutect2, varscan2
- CAVIN2 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV58423185; called by muse, mutect2
- CCDC92 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs1016337164, COSV99435684; called by muse, mutect2, varscan2
- CEP112 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV67136055; called by muse, mutect2, varscan2
- CHD1 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV52336695; called by muse, mutect2, varscan2
- CIZ1 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs767617433, COSV99476984; called by muse, mutect2, varscan2
- COL2A1 | c.3886+2T>C p.X1296_splice | Splice Site (SNP) | VAF 37/143 reads (26%) | catalogued as CS063284, COSV100476980; called by muse, mutect2, varscan2
- CPAMD8 | c.1057G>T p.A353S (on ENST00000651564; = p.A306S on NM_015692.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as COSV99359548; called by muse, mutect2
- CSF2RA | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs767686310, COSV62623408; called by muse, mutect2, varscan2
- DARS2 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766714463, CM143080, COSV53405671; called by muse, mutect2, varscan2
- DDX58 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV65882048; called by muse, mutect2, varscan2
- DEFB116 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV68721888; called by muse, mutect2, varscan2
- DFFA | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV65476942; called by muse, mutect2, varscan2
- DIP2C | c.740-1G>A p.X247_splice | Splice Site (SNP) | VAF 39/327 reads (12%) | catalogued as COSV99792687; called by muse, mutect2, varscan2
- DMD | c.834C>A p.I278= | Splice Region (SNP) | VAF 143/270 reads (53%) | catalogued as COSV55853179; called by muse, mutect2, varscan2
- DNTTIP2 | c.2028C>A p.Y676* | Nonsense Mutation (SNP) | VAF 61/403 reads (15%) | catalogued as COSV100785181; called by muse, mutect2, varscan2
- EDNRB | c.383C>T p.P128L (on ENST00000377211 / NM_001201397.1; = p.P38L on NM_000115.5) | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs779495524, COSV100526830; called by muse, mutect2, varscan2
- EGFR | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV51769747, COSV51801711; called by muse, mutect2, varscan2
- ERBB4 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV99627996, COSV99633316; called by muse, mutect2, varscan2
- FBXW7 | c.1015A>T p.R339* (on ENST00000281708 / NM_001349798.2; = p.R259* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 303/1012 reads (30%) | catalogued as COSV99658855; called by muse, varscan2
- FLG | c.1572A>T p.R524S | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.298); catalogued as rs1354863547, COSV100911803; called by muse, mutect2, varscan2
- FTO | c.290T>G p.I97S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV101150675; called by muse, mutect2, varscan2
- GC | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 99/415 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV56735231; called by muse, mutect2, varscan2
- GC | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99909930; called by muse, mutect2
- GPR78 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs766883899, COSV101223919; called by muse, varscan2
- GRID1 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753413551, COSV100025114, COSV60031971; called by muse, mutect2
- GRID2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370298520; called by muse, mutect2, varscan2
- GRIK3 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV100901770; called by muse, mutect2, varscan2
- GRIN2A | c.2755A>G p.K919E | Missense Mutation (SNP) | VAF 80/727 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100410430; called by muse, mutect2, varscan2
- GSDMB | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100522834; called by muse, mutect2, varscan2
- GSDME | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs768736799, COSV100742388; ClinVar: uncertain significance; called by muse, mutect2
- HEPN1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs183886198, COSV53428510; called by muse, mutect2, varscan2
- HERC5 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as COSV99987927; called by muse, mutect2, varscan2
- IDE | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 133/738 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.744); catalogued as COSV99794155; called by mutect2, varscan2
- ITPR3 | c.7588_7590del p.K2530del | In Frame Del (DEL) | VAF 12/130 reads (9%) | catalogued as rs1299181551; called by pindel, varscan2
- KANSL1L | c.2565-2A>C p.X855_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99910731; called by muse, mutect2, varscan2
- KIRREL3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs200090559; called by muse, mutect2, varscan2
- KLHL1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100917689; called by muse, mutect2
- KLHL34 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101069960; called by mutect2, varscan2
- KRT33A | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs773925887, COSV50365429; called by muse, mutect2, varscan2
- LUZP2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 100/483 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs138554284; called by muse, mutect2, varscan2
- MFSD2B | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs762530433, COSV57853867; called by muse, mutect2, varscan2
- MTMR12 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99373780; called by muse, mutect2, varscan2
- NFASC | c.2317C>T p.R773* (on ENST00000339876 / NM_001378329.1; = p.R769* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as rs770018291, COSV100363936; called by muse, mutect2, varscan2
- NOL9 | c.1459A>G p.S487G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1557784368, COSV100891487; called by muse, mutect2, varscan2
- NPHP3 | c.982A>C p.M328L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58128481; called by muse, mutect2, varscan2
- NPRL3 | c.1606C>T p.R536W (on ENST00000611875 / NM_001077350.3; = p.R511W on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769327693, COSV54737285; called by muse, mutect2, varscan2
- OR13C5 | c.817T>A p.L273M | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV66164122; called by muse, mutect2, varscan2
- OR2T6 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1218675147, COSV63215670; called by muse, mutect2, varscan2
- OR7C1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.15); catalogued as rs1049317748, COSV99934916; called by muse, mutect2, varscan2
- OR8D2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs770093735, COSV62488017; called by muse, mutect2, varscan2
- PAPPA | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV100074689, COSV60277807; called by muse, mutect2, varscan2
- PCDH15 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV57261949; called by muse, varscan2
- PCDHA1 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as COSV65373699; called by muse, mutect2, varscan2
- PCOLCE | c.1173dup p.M392Hfs*81 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | catalogued as rs777844367; called by mutect2, varscan2
- PDLIM5 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV100524031; called by muse, mutect2, varscan2
- POLI | c.1720A>G p.K574E | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1216711247, COSV54187605; called by muse, mutect2, varscan2
- PROKR1 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs201464916, COSV58136498; called by muse, mutect2, varscan2
- PTPN12 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50359298, COSV99950507; called by muse, mutect2
- PXN | c.15C>T p.D5= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs200236405; called by muse, mutect2, varscan2
- RAB3C | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs775390478, COSV51431637; called by muse, mutect2, varscan2
- RTL9 | c.1823C>A p.S608Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV101511740; called by muse, mutect2, varscan2
- RYR2 | c.1408T>G p.L470V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV100771837; called by muse, mutect2
- RYR3 | c.11238C>G p.N3746K (on ENST00000389232; = p.N3747K on NM_001036.6) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101213201; called by muse, mutect2, varscan2
- SHQ1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as rs375075276; called by muse, mutect2, varscan2
- SLC26A9 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 105/379 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1033341954, COSV61600758; called by muse, mutect2, varscan2
- SLITRK5 | c.1629G>T p.L543F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100280976; called by muse, mutect2, varscan2
- SNX2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV65347638; called by muse, mutect2, varscan2
- SPIDR | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99855521; called by muse, mutect2
- SPTA1 | c.5444T>G p.L1815W | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367644017, COSV100935197; called by muse, mutect2, varscan2
- STXBP5L | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875196; called by muse, mutect2, varscan2
- SYNE1 | c.20220T>G p.N6740K (on ENST00000367255 / NM_182961.4; = p.N6669K on NM_033071.3) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99571557; called by muse, mutect2, varscan2
- TCEA1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 192/336 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs199869556, COSV67172022; called by muse, mutect2, varscan2
- TMLHE | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV57686181; called by muse, mutect2, varscan2
- TMTC1 | c.922G>T p.V308L (on ENST00000539277 / NM_001193451.2; = p.V200L on NM_175861.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99760250; called by muse, mutect2, varscan2
- TMTC1 | c.479C>T p.A160V (on ENST00000539277 / NM_001193451.2; = p.A52V on NM_175861.3) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779339155, COSV55488366, COSV99758642; called by muse, mutect2, varscan2
- UGT3A2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV99236614; called by muse, mutect2, varscan2
- UNC13C | c.4619T>A p.M1540K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as COSV52883020, COSV99520244; called by muse, mutect2, varscan2
- VAMP7 | c.647G>C p.S216T | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52901191; called by muse, mutect2, varscan2
- WDPCP | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705875; called by muse, mutect2, varscan2
- WDR36 | c.2464G>C p.A822P | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.901); catalogued as COSV101550988; called by muse, mutect2, varscan2
- ZNF419 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 84/517 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99692420; called by muse, varscan2
- ZNF521 | c.137T>A p.V46E | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV100832757; called by muse, mutect2, varscan2
- ZZZ3 | c.1731T>A p.F577L | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100890377; called by muse, mutect2, varscan2
- KIR3DL2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2
- RHAG | c.591del p.H198Mfs*15 | Frame Shift Del (DEL) | VAF 35/213 reads (16%) | called by mutect2, pindel, varscan2
- SMOX | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.85); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM24 | c.3025dup p.R1009Kfs*10 (on ENST00000343526 / NM_015905.3; = p.R975Kfs*10 on NM_003852.4) | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.3498G>A p.P1166= | Silent (SNP) | VAF 52/510 reads (10%) | catalogued as rs779626374, COSV61316098; called by muse, mutect2
- ATP1A4 | c.2724C>T p.Y908= | Silent (SNP) | VAF 45/460 reads (10%) | catalogued as rs555177353, COSV63625393; called by muse, mutect2, varscan2
- CFAP221 | c.2262C>T p.D754= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as rs371548429; called by muse, mutect2, varscan2
- CILP | c.3276C>T p.L1092= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs144863148; called by mutect2, varscan2
- DNAJC9 | c.213C>T p.D71= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs760980554, COSV54349760; called by muse, mutect2, varscan2
- DNASE2 | c.873C>T p.S291= | Silent (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- DSPP | c.1395C>A p.P465= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99217631; called by muse, mutect2, varscan2
- EMC1 | c.1281T>C p.D427= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs1298730677, COSV64345148; called by muse, mutect2, varscan2
- ETV1 | c.270A>G p.K90= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV54136575; called by muse, mutect2, varscan2
- FAM193B | c.429G>A p.Q143= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV61557388; called by muse, mutect2, varscan2
- FRAS1 | c.777G>A p.L259= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV53588321; called by muse, mutect2, varscan2
- FZD7 | c.1383C>T p.T461= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs1000638888, COSV53808179; called by muse, mutect2, varscan2
- JADE1 | c.936G>A p.A312= | Silent (SNP) | VAF 81/226 reads (36%) | catalogued as rs907816835, COSV56904184; called by muse, mutect2, varscan2
- KLF2 | c.1026G>A p.S342= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs890385238, COSV99934210; called by muse, mutect2, varscan2
- MECP2 | c.1002A>G p.K334= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57654641; called by muse, mutect2, varscan2
- MTERF3 | c.1074G>A p.R358= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as COSV54629078; called by muse, mutect2, varscan2
- NEUROD1 | c.825G>A p.P275= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs980694279, COSV54548096; called by muse, mutect2, varscan2
- NLRP1 | c.1371G>A p.T457= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs756445565, COSV52558226; called by muse, mutect2, varscan2
- POLR3E | c.246C>T p.D82= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs764860863, COSV55398871; called by muse, mutect2, varscan2
- PROS1 | c.618T>C p.S206= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ROR2 | c.1623C>T p.G541= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs746790764, COSV65216315; called by muse, mutect2, varscan2
- SFMBT2 | c.366C>T p.D122= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs554112272, COSV62806954; called by muse, varscan2
- SSU72P8 | c.75C>T p.I25= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2
- ZNF804B | c.2175T>A p.T725= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV60815809; called by muse, mutect2, varscan2
- HOXC4 | c.-124+16593C>T | Intron (SNP) | VAF 39/169 reads (23%) | catalogued as COSV99679122; called by muse, mutect2, varscan2
- VPS11 | c.-535G>C | 5'UTR (SNP) | VAF 26/236 reads (11%) | catalogued as rs782468120, COSV56183824; called by muse, mutect2, varscan2
